Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A20X, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A20X-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Bladder cancer.

PROCEDURE: Total cystectomy.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION THERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

FINAL DIAGNOSIS:

PART 1:

URETER, LEFT DISTAL MARGIN, BIOPSY -

A. SEGMENT OF URETER LINED BY BENIGN UROTHELIAL MUCOSA.

B. NO UROTHELIAL CARCINOMA IN SITU (CIS) NOR INVASIVE UROTHELIAL CARCINOMA SEEN.

Collection Date:

PART 2:

URETER, RIGHT DISTAL MARGIN, BIOPSY -

A. SEGMENT OF URETER LINED BY BENIGN UROTHELIAL MUCOSA.

B. NO UROTHELIAL CARCINOMA IN SITU (CIS) NOR INVASIVE UROTHELIAL CARCINOMA SEEN.

PART 3:

LYMPH NODES, PRESACRAL, EXCISION -

A. FIBROFATTY TISSUE ONLY.

B. NO LYMPH NODE IDENTIFIED.

C. NO TUMOR SEEN.

PART 4:

LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF CARCINOMA IN ONE (0/1) LYMPH NODE EXAMINED.

PART 5:

LYMPH NODES, RIGHT PELVIC, EXCISION -

METASTATIC UROTHELIAL CARCINOMA IN 2 (2/11) LYMPH NODES EXAMINED.

PART 6:

BLADDER, RADICAL CYSTOPROSTATECTOMY -

A. INVASIVE UROTHELIAL (TRANSITIONAL CELL) CARCINOMA (5.0 CM), HIGH GRADE (WHO/ISUP), WITH SQUAMOUS FEATURES.

B. THE CARCINOMA INVADES THROUGH THE DETRUSOR MUSCLE AND EXTENDS INTO THE PERIVESICLE FAT.

C. TUMOR EXTENDS INTO THE PROSTATIC STROMA.

D. CARCINOMA IS SEEN PRESENT WITHIN 0.1CM OF THE INKED SURGICAL MARGINS (SECTION 6H) IN THE REGION OF THE RIGHT LATERAL WALL.

E. ONE LYMPH NODE POSITIVE FOR CARCINOMA (1/1).

F. UROTHELIAL CARCINOMA IN SITU IS IDENTIFIED.

G. PERINEURAL INVASION IS IDENTIFIED.

H. MULTIFOCAL ANGIOLYMPHATIC INVASION IS IDENTIFIED.

I. TNM PATHOLOGIC STAGING = T4 N2 MX.

J. CYSTITIS CYSTICA AND SQUAMOUS METAPLASIA ARE SEEN.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE:

Radical cystoprostatectomy

TUMOR SITE:

Right lateral wall, Left lateral wall, Anterior wall, Posterior wall, Dome

TUMOR SIZE:

Greatest dimension: 5.0 cm

HISTOLOGIC TYPE:

Urothelial (transitional cell) carcinoma with squamous differentiation

ASSOCIATED EPITHELIAL LESIONS:

None identified

HISTOLOGIC GRADE:

Urothelial carcinoma - High-grade

TUMOR CONFIGURATION:

Solid/nodule, Ulcerated

PATHOLOGIC STAGING (pTNM):

pT4a

pN2

Number of nodes examined: 12

Number of nodes involved: 3

pMX

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of tumor from closest margin: 1.0 mm

Margin: RIGHT LATERAL

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L):

Present

DIRECT EXTENSION OF INVASIVE TUMOR:

Perivesical fat
Prostatic stroma

ADDITIONAL PATHOLOGIC FINDINGS:

Cystitis cystica glandularis

1CD-0-3

Carcinoma, urothelial 8/20/3

Sites bladder, dome C67.1 for 4/7/11

Source: NCI Genomic Data Commons file 404160b3-bbc9-4ec2-a061-50f4e7b5c2f5 (TCGA-BT-A20X.60D4B255-2F73-4F45-83D5-68B8CC422D1C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).